Somatic mutation profile of tumor specimen TCGA-HC-A8CY-01A (aliquot TCGA-HC-A8CY-01A-11D-A364-08) from TCGA case TCGA-HC-A8CY, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.4 years (23,154 days).
Specimen TCGA-HC-A8CY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c23811f-51ab-4e68-b1e8-012875c75d3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A8CY-10A (Blood Derived Normal), aliquot TCGA-HC-A8CY-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f89cb0c-4297-486f-95c0-50eb0b19a05e

The open-access MAF lists 32 somatic variants for this specimen: 22 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 17, Silent 10, Nonsense Mutation 2, Frame Shift Del 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMZ1 | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV100406288; called by muse, mutect2, varscan2
- CGNL1 | c.1076A>C p.K359T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99847856; called by muse, mutect2, varscan2
- DLG2 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99713987; called by muse, mutect2, varscan2
- EFNA3 | c.269T>C p.M90T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1453505920, COSV100860809; called by muse, mutect2, varscan2
- EPB41L3 | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs143942399; called by muse, mutect2, varscan2
- EPN1 | c.1390A>G p.T464A (on ENST00000270460 / NM_001321263.1; = p.T438A on NM_013333.3) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1416191391, COSV99321743; called by muse, mutect2, varscan2
- GRIP2 | c.2968G>T p.E990* (on ENST00000619221; = p.E893* on NM_001080423.4) | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs770978164, COSV99817124; called by muse, varscan2
- GZMK | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554044709, COSV99140853; called by muse, mutect2, varscan2
- IFIT2 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV51080849, COSV99260096; called by muse, mutect2, varscan2
- KIAA0753 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.602); catalogued as COSV100810554; called by muse, mutect2
- LTBP3 | c.2534A>C p.N845T | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.104); catalogued as COSV99533940; called by muse, mutect2
- MAP2 | c.3519A>G p.I1173M | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.5); catalogued as rs201672675, COSV99558940; called by muse, mutect2, varscan2
- MUC16 | c.34951C>T p.P11651S | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.061); catalogued as rs750858646, COSV101199105; called by muse, mutect2
- NALCN | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs759934018, COSV99213939; called by muse, mutect2, varscan2
- PDGFD | c.288C>A p.D96E | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100158504; called by muse, mutect2, varscan2
- RAD51D | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as rs730881948, COSV100239077; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TKTL2 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs1380952743, COSV54919623; called by muse, mutect2, varscan2
- TRAC | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750169372; called by muse, mutect2, varscan2
- ZBBX | c.690A>G p.V230= | Splice Region (SNP) | VAF 34/121 reads (28%) | catalogued as rs1267878866, COSV100283605; called by muse, mutect2, varscan2
- ZC3H13 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 12/95 reads (13%) | catalogued as rs1292804126, COSV54449998; called by muse, mutect2, varscan2
- FMR1NB | c.386dup p.F130Lfs*17 | Frame Shift Ins (INS) | VAF 8/60 reads (13%) | called by mutect2, pindel, varscan2
- HDLBP | c.3759_3792del p.F1253Lfs*30 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel
- ATP2C1 | c.1599G>T p.L533= | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as COSV100146502; called by muse, mutect2, varscan2
- CD163 | c.318C>T p.S106= | Silent (SNP) | VAF 52/109 reads (48%) | catalogued as COSV63131673; called by muse, mutect2, varscan2
- CHRNB2 | c.405C>T p.A135= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as rs777250519, COSV63809602; called by muse, mutect2, varscan2
- FTMT | c.306C>T p.S102= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV100360285; called by muse, mutect2
- GRM7 | c.846C>T p.A282= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs761307351, COSV100736030; called by muse, mutect2, varscan2
- KRT86 | c.1203C>T p.I401= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as rs755372953, COSV53293240; called by muse, mutect2, varscan2
- NELL1 | c.402G>A p.K134= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100120272; called by muse, mutect2, varscan2
- SORCS2 | c.3447C>T p.N1149= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs780275829, COSV100212085; called by muse, mutect2, varscan2
- WIF1 | c.579T>C p.N193= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs931044269, COSV99682711; called by muse, mutect2, varscan2
- ZNF536 | c.1005C>T p.N335= | Silent (SNP) | VAF 7/150 reads (5%) | catalogued as rs1023728749, COSV100834950, COSV62831700; called by muse, mutect2
